Somatic mutation profile of tumor specimen TCGA-DU-7019-01A (aliquot TCGA-DU-7019-01A-11D-2024-08) from TCGA case TCGA-DU-7019, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 39.1 years (14,279 days).
Specimen TCGA-DU-7019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c33d2ce3-f452-40d4-97c8-69bd380544fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7019-10A (Blood Derived Normal), aliquot TCGA-DU-7019-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c385fed1-525b-4f40-8c19-e76b190fa824

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, In Frame Del 5, Frame Shift Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMARCA4 | c.1636_1638del p.K546del | In Frame Del (DEL) | VAF 50/188 reads (27%) | hotspot (GDC flag); catalogued as rs876657378; called by pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 56/77 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM2 | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV99698060; called by muse, mutect2
- CACNA1G | c.4747A>C p.S1583R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV61740660; called by muse, mutect2
- CBARP | c.1066C>T p.R356W (on ENST00000382477; = p.R336W on NM_152769.3) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779114359, COSV53067800; called by muse, mutect2, varscan2
- CNKSR2 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54263725, COSV54267532; called by muse, mutect2, varscan2
- DNAH7 | c.4372T>C p.Y1458H | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56788945; called by muse, mutect2
- KCNJ15 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772620107, COSV60810335; called by muse, mutect2
- KRTAP19-2 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.166); catalogued as COSV61855193; called by muse, mutect2
- LILRA1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs555171577, COSV52185577; called by muse, varscan2
- LRRC8A | c.1691A>G p.D564G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV52189610; called by muse, mutect2, varscan2
- MAP3K12 | c.2166_2168del p.E723del | In Frame Del (DEL) | VAF 20/144 reads (14%) | catalogued as rs1272159984; called by pindel, varscan2
- PRPS1L1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as rs369368833; called by muse, mutect2, varscan2
- PVR | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs778599347, COSV51824639; called by muse, mutect2, varscan2
- SCN5A | c.4250C>T p.T1417I (on ENST00000333535 / NM_198056.3; = p.T1416I on NM_000335.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61141857; called by muse, mutect2, varscan2
- SLC24A3 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60134378; called by muse, mutect2, varscan2
- TBC1D4 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV66492586; called by muse, mutect2, varscan2
- WRAP53 | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV53690165; called by muse, mutect2, varscan2
- CPEB4 | c.838_841del p.K280Pfs*41 | Frame Shift Del (DEL) | VAF 43/330 reads (13%) | called by mutect2, pindel, varscan2
- HAP1 | c.1720del p.A574Lfs*5 (on ENST00000310778 / NM_001367460.1; = p.A522Lfs*5 on NM_177977.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 70/384 reads (18%) | called by mutect2, pindel, varscan2
- KCNG1 | c.349_351del p.F117del | In Frame Del (DEL) | VAF 10/57 reads (18%) | called by pindel, varscan2
- NEB | c.2566_2569del p.I856Efs*15 | Frame Shift Del (DEL) | VAF 13/130 reads (10%) | called by mutect2, pindel, varscan2
- SNX16 | c.78_80del p.R26del | In Frame Del (DEL) | VAF 34/170 reads (20%) | called by pindel, varscan2
- TPR | c.5351_5353del p.P1784del | In Frame Del (DEL) | VAF 21/100 reads (21%) | called by mutect2, pindel, varscan2
- TRPV3 | c.45_46del p.R15Sfs*36 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by pindel, varscan2
- ZNF224 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- CLCNKB | c.1402C>T p.L468= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs1424328306, COSV65161971; called by muse, mutect2, varscan2
- CRACD | c.2457G>A p.S819= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs766344051, COSV51725705; called by muse, mutect2, varscan2
- DNAH10 | c.6063C>T p.P2021= (on ENST00000409039; = p.P1960= on NM_207437.3) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs765440145, COSV69003104; called by muse, mutect2, varscan2
- EIF3L | c.837C>T p.R279= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV67740192; called by muse, mutect2, varscan2
- NWD1 | c.1287C>T p.F429= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs372894087; called by muse, mutect2, varscan2
- OR3A2 | c.624C>T p.L208= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs1372503690, COSV68695325; called by muse, mutect2, varscan2
- UBE4A | c.183C>T p.F61= | Silent (SNP) | VAF 84/251 reads (33%) | catalogued as rs753564653, COSV52802525; called by muse, mutect2, varscan2
- ZC3H4 | c.2058C>T p.P686= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1322700885, COSV53417574; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2205C>T p.A735= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs373942547; called by muse, mutect2, varscan2
